Somatic mutation profile of tumor specimen C3N-01851-01 (aliquot CPT0186100006) from CPTAC case C3N-01851, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 47.9 years (17,508 days).
Specimen C3N-01851-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 724cdc2c-46ba-4808-b285-812fb10ee747.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01851-31 (Blood Derived Normal), aliquot CPT0186120002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/86f7760c-b7af-4d8b-8e2a-5226f3e36f82

The open-access MAF lists 43 somatic variants for this specimen: 32 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 10, Frame Shift Del 3, Nonsense Mutation 3, Splice Site 2, Frame Shift Ins 1, 3'UTR 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 52/341 reads (15%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.452C>A p.P151H | Missense Mutation (SNP) | VAF 60/392 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as rs1057520000, COSV52677206, COSV52707835, COSV52811105; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ACHE | c.686C>T p.T229M | Missense Mutation (SNP) | VAF 107/711 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs781493866, COSV53820266; called by muse, mutect2, varscan2
- ATRX | c.2422C>T p.R808* | Nonsense Mutation (SNP) | VAF 10/24 reads (42%) | catalogued as COSV64874953; called by muse, mutect2, varscan2
- C6orf118 | c.253C>T p.R85W | Missense Mutation (SNP) | VAF 27/191 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as rs200810534; called by muse, mutect2, varscan2
- CD69 | c.64+1G>T p.X22_splice | Splice Site (SNP) | VAF 8/50 reads (16%) | catalogued as COSV57303934; called by muse, mutect2, varscan2
- CHD2 | c.2537G>A p.R846Q | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1429234959, COSV67708399; called by muse, mutect2, varscan2
- FKBP9 | c.1100del p.P367Lfs*19 | Frame Shift Del (DEL) | VAF 42/249 reads (17%) | catalogued as rs1562574598; called by mutect2, pindel, varscan2
- MUC16 | c.18141G>T p.M6047I | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as COSV101200726; called by muse, mutect2, varscan2
- NF1 | c.1513A>T p.K505* | Nonsense Mutation (SNP) | VAF 6/33 reads (18%) | catalogued as CS982283, COSV62215710; called by muse, mutect2, varscan2
- NOTCH1 | c.4373C>T p.A1458V | Missense Mutation (SNP) | VAF 51/278 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.077); catalogued as rs374352922, COSV53051082; called by muse, mutect2, varscan2
- OR4C16 | c.837del p.L280Sfs*4 | Frame Shift Del (DEL) | VAF 3/19 reads (16%) | catalogued as COSV100113816; called by pindel, varscan2
- PPM1D | c.1372C>T p.R458* | Nonsense Mutation (SNP) | VAF 16/67 reads (24%) | catalogued as rs773389405, CM137522, COSV59954743; called by muse, mutect2, varscan2
- RBM47 | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 40/239 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs1014955331; called by muse, mutect2, varscan2
- SCN5A | c.4213G>A p.V1405M (on ENST00000333535 / NM_198056.3; = p.V1404M on NM_000335.5) | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199473239, CM023679, CM100715, COSV61119508; ClinVar: not provided; called by muse, mutect2
- SYDE2 | c.863G>A p.R288H | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.92); catalogued as rs946899293, COSV52314878; called by muse, mutect2, varscan2
- TEPSIN | c.277C>T p.R93C | Missense Mutation (SNP) | VAF 71/499 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs375320091; called by muse, mutect2, varscan2
- TMEM72 | c.210-1G>C p.X70_splice | Splice Site (SNP) | VAF 27/142 reads (19%) | catalogued as COSV101273596; called by muse, mutect2
- ANK3 | c.4768T>C p.Y1590H | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CYP4F2 | c.547T>C p.S183P | Missense Mutation (SNP) | VAF 42/219 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- DSC1 | c.1981A>G p.T661A | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGLL1 | c.342del p.S115Rfs*23 | Frame Shift Del (DEL) | VAF 58/296 reads (20%) | called by mutect2, pindel, varscan2
- KRTAP16-1 | c.548T>A p.L183H | Missense Mutation (SNP) | VAF 69/427 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- LAPTM4A | c.55T>G p.C19G | Missense Mutation (SNP) | VAF 51/361 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- NCK2 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 119/591 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- NPC1L1 | c.257dup p.N86Kfs*33 | Frame Shift Ins (INS) | VAF 50/444 reads (11%) | called by mutect2, pindel, varscan2
- OR1M1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); called by muse, mutect2
- OR5K4 | c.556A>G p.R186G | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- SIGLEC7 | c.178C>T p.P60S | Missense Mutation (SNP) | VAF 87/513 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- SPANXB1 | c.84C>A p.N28K | Missense Mutation (SNP) | VAF 98/676 reads (14%) | SIFT tolerated, low confidence (0.3); called by muse, mutect2, varscan2
- TPTE | c.778T>A p.Y260N (on ENST00000618007 / NM_199261.4; = p.Y242N on NM_199259.4) | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- WASHC1 | c.1054C>T p.P352S | Missense Mutation (SNP) | VAF 148/1330 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, varscan2
- AADACL4 | c.1098C>T p.R366= | Silent (SNP) | VAF 23/212 reads (11%) | catalogued as rs371094883; called by muse, mutect2, varscan2
- AGXT2 | c.1116G>A p.A372= | Silent (SNP) | VAF 56/300 reads (19%) | catalogued as rs1207970057, COSV51485094; called by muse, mutect2, varscan2
- COL11A2 | c.2493G>A p.S831= (on ENST00000341947 / NM_080680.3; = p.S724= on NM_080679.2) | Silent (SNP) | VAF 140/684 reads (20%) | catalogued as rs760351554; called by muse, mutect2, varscan2
- FADS6 | c.912T>C p.H304= | Silent (SNP) | VAF 52/511 reads (10%) | catalogued as rs1002415494, COSV59602965; called by muse, mutect2, varscan2
- LGSN | c.1062G>A p.A354= | Silent (SNP) | VAF 12/128 reads (9%) | catalogued as rs138743031; called by muse, mutect2
- MST1R | c.1092T>C p.S364= | Silent (SNP) | VAF 81/511 reads (16%) | called by muse, mutect2, varscan2
- MYO15A | c.1134C>T p.V378= | Silent (SNP) | VAF 162/884 reads (18%) | called by muse, mutect2, varscan2
- PIAS4 | c.108C>T p.H36= | Silent (SNP) | VAF 119/486 reads (24%) | catalogued as rs141222368; called by muse, mutect2, varscan2
- TMEM184B | c.39G>A p.A13= | Silent (SNP) | VAF 48/271 reads (18%) | catalogued as rs376870547; called by muse, mutect2, varscan2
- TRPC3 | c.738C>T p.Y246= (on ENST00000379645 / NM_001366479.2; = p.Y173= on NM_003305.2) | Silent (SNP) | VAF 23/510 reads (5%) | catalogued as COSV53381021; called by muse, mutect2
- DEFA6 | c.*2G>A | 3'UTR (SNP) | VAF 3/14 reads (21%) | catalogued as rs1195578969; called by muse, mutect2
